Somatic mutation profile of tumor specimen TARGET-20-PATFMR-09A (aliquot TARGET-20-PATFMR-09A-01D) from TARGET case TARGET-20-PATFMR, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.3 years (5,586 days).
Specimen TARGET-20-PATFMR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c9523b5-628d-4b7e-a6c2-7c389a1bcd6f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATFMR-14A (Bone Marrow Normal), aliquot TARGET-20-PATFMR-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d9576cf-a413-4dac-8281-49a06c557ccc

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPI1 | c.611_624del p.K204Tfs*79 | Frame Shift Del (DEL) | VAF 36/121 reads (30%) | called by mutect2, pindel, varscan2
- SPI1 | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
